Somatic mutation profile of tumor specimen TCGA-G8-6326-01A (aliquot TCGA-G8-6326-01A-11D-2210-10) from TCGA case TCGA-G8-6326, project TCGA-DLBC (Lymphoid Neoplasm Diffuse Large B-cell Lymphoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Diffuse large B-cell lymphoma, NOS; Tissue or organ of origin: Specified parts of peritoneum; Age at diagnosis: 52.7 years (19,238 days).
Specimen TCGA-G8-6326-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) aedfcf75-942d-47b0-85b8-b8d095c11bd7.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-G8-6326-10A (Blood Derived Normal), aliquot TCGA-G8-6326-10A-01D-2210-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/2e9bd269-a8f7-46ec-86ad-d75828867d06

The open-access MAF lists 1 somatic variant for this specimen: 1 protein-altering or splice-affecting.
By variant classification: Missense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- USP34 | c.7618G>C p.D2540H | Missense Mutation (SNP) | VAF 5/79 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as COSV68407838; called by muse, mutect2
